Somatic mutation profile of tumor specimen TCGA-OR-A5LI-01A (aliquot TCGA-OR-A5LI-01A-11D-A30A-10) from TCGA case TCGA-OR-A5LI, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 42.5 years (15,536 days).
Specimen TCGA-OR-A5LI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be59933d-be70-42a1-a661-0bd3d9f3160e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LI-10A (Blood Derived Normal), aliquot TCGA-OR-A5LI-10A-01D-A30A-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/257497cc-c43d-45ea-8131-94db192302d0

The open-access MAF lists 56 somatic variants for this specimen: 44 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 10, Nonsense Mutation 3, 5'UTR 1, In Frame Del 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.6592A>G p.T2198A | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as COSV54953181; called by muse, mutect2, varscan2
- AFP | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.96); PolyPhen benign (0.266); catalogued as COSV56924676; called by muse, mutect2, varscan2
- CXCL9 | c.236C>G p.S79* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as rs769576198, COSV53578725; called by muse, mutect2, varscan2
- KIAA1109 | c.8695A>G p.I2899V | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as rs1236596136; called by muse, mutect2, varscan2
- KIF23 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs992414764, COSV99532324; called by muse, mutect2, varscan2
- KIRREL1 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63285253; called by muse, mutect2, varscan2
- L3MBTL4 | c.1290del p.E430Dfs*15 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs1177327637; called by mutect2, pindel, varscan2
- LAMA1 | c.2557G>A p.G853S | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.817); catalogued as rs1247550665, COSV67533182; called by muse, mutect2, varscan2
- MRC1 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 73/349 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.859); catalogued as rs1018179715; called by muse, mutect2, varscan2
- PLXNA1 | c.3953G>A p.G1318D | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs868678696; called by muse, mutect2, varscan2
- PPFIA2 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs762675207, COSV100335545; called by muse, mutect2, varscan2
- SAMD7 | c.1148C>A p.S383* | Nonsense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as COSV59418473; called by muse, mutect2, varscan2
- SEC16A | c.3961G>A p.D1321N | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs764422846, COSV99260164; called by muse, mutect2, varscan2
- SELE | c.1343T>C p.I448T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs199700651, COSV100324837; called by muse, mutect2, varscan2
- SEMA4G | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 64/325 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs764503702, COSV52966682; called by muse, mutect2, varscan2
- SPHKAP | c.2234G>A p.R745K | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV60871018; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3388G>A p.D1130N | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs770124427; called by muse, mutect2, varscan2
- TRIM51 | c.1208C>G p.P403R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV104392278; called by muse, mutect2, varscan2
- TSEN34 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs373921569; called by muse, mutect2
- ABCB11 | c.427A>G p.S143G | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKH | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ANKRD34B | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- ARHGAP6 | c.1194T>G p.D398E | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- BDP1 | c.5432T>G p.L1811R | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- BTAF1 | c.522G>C p.L174F | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CD93 | c.1372T>G p.W458G | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- CDC16 | c.1337C>G p.P446R | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLCN2 | c.1391T>G p.V464G | Missense Mutation (SNP) | VAF 104/413 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, varscan2
- DSC2 | c.1976C>A p.S659Y | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- FBXO16 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- FN1 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA2 | c.1916A>G p.D639G | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MTR | c.3607T>A p.L1203I | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- NOCT | c.1092G>A p.W364* | Nonsense Mutation (SNP) | VAF 47/162 reads (29%) | called by muse, mutect2, varscan2
- OPRL1 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- PTPN11 | c.722A>G p.D241G | Missense Mutation (SNP) | VAF 69/336 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RHOB | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- RMDN2 | c.821A>T p.E274V (on ENST00000354545 / NM_001322212.2; = p.E452V on NM_144713.5) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- SBNO2 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SGK1 | c.264_266del p.S89del | In Frame Del (DEL) | VAF 14/87 reads (16%) | called by pindel, varscan2
- SMARCA5 | c.2840A>G p.Y947C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TAFA5 | c.203G>A p.C68Y (on ENST00000402357 / NM_001082967.3; = p.C61Y on NM_015381.7) | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VNN3 | c.811C>G p.P271A | Missense Mutation (SNP) | VAF 52/239 reads (22%) | PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ZC3H6 | c.1018T>C p.Y340H | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP13A1 | c.1956C>T p.A652= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs769982276; called by muse, mutect2, varscan2
- BEX4 | c.39C>T p.N13= | Silent (SNP) | VAF 73/161 reads (45%) | catalogued as COSV65516042; called by muse, mutect2, varscan2
- HIPK1 | c.594G>T p.R198= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- KCNH4 | c.1353G>A p.A451= | Silent (SNP) | VAF 57/200 reads (29%) | catalogued as rs140040426; called by muse, mutect2, varscan2
- LRP1 | c.2571C>T p.G857= | Silent (SNP) | VAF 50/243 reads (21%) | catalogued as rs761500509, COSV54510886; called by muse, mutect2, varscan2
- MCOLN1 | c.1245C>T p.I415= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as rs1302332702; called by muse, mutect2, varscan2
- MSL1 | c.1503T>C p.S501= (on ENST00000398532 / NM_001365919.1; = p.S238= on NM_001012241.2) | Silent (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- NPHS1 | c.96G>A p.R32= | Silent (SNP) | VAF 58/290 reads (20%) | called by muse, mutect2, varscan2
- NRXN3 | c.3024C>T p.L1008= (on ENST00000335750 / NM_001330195.2; = p.L635= on NM_004796.6) | Silent (SNP) | VAF 48/232 reads (21%) | catalogued as rs564964171; called by muse, mutect2, varscan2
- ZNF212 | c.990G>A p.Q330= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100242259; called by muse, mutect2, varscan2
- DAB1 | c.-1G>C | 5'UTR (SNP) | VAF 13/68 reads (19%) | catalogued as COSV100140792; called by muse, mutect2, varscan2
- MIR542 | n.6C>G | RNA (SNP) | VAF 24/40 reads (60%) | called by muse, mutect2, varscan2
